EXCEPTIONAL_RESPONDERS case ER-ABPA — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f9470146-dda9-4576-b143-c1e6a8d2de6c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Alive.

Diagnoses (1)
1. Small cell carcinoma, NOS: ICD-O-3 morphology code: 8041/3; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 45.3 years (16,529 days); Year of diagnosis: 2007; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Days to last follow up: 2,782 days (7.6 years); Days to best overall response: 0 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Cisplatin; Days to treatment start: 12 days; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Vinblastine Sulfate; Days to treatment start: 12 days; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Bleomycin; Days to treatment start: 13 days; Days to treatment end: 159 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Days to treatment start: 13 days; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Doxorubicin Hydrochloride + Etoposide; Days to treatment start: 14 days; Days to treatment end: 160 days.

Follow-up (1 entry)
- Days to follow up: 2,782 days (7.6 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 2,782 days (7.6 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABPA-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Preservation method: FFPE.
  Slide ER-ABPA-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
